FM case AD1880 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Small intestine.
https://portal.gdc.cancer.gov/cases/1446feb0-4697-497e-b7e9-21774cb69e47

Male, 66.4 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the duodenum; metastasis biopsied or resected from the pancreas. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
